Somatic mutation profile of tumor specimen TCGA-13-0916-01A (aliquot TCGA-13-0916-01A-01W-0420-08) from TCGA case TCGA-13-0916, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.8 years (18,189 days).
Specimen TCGA-13-0916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3857627a-af9a-4c8e-b00c-4182ec8ae451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0916-10A (Blood Derived Normal), aliquot TCGA-13-0916-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5788e994-a06b-43ce-be6a-018af892fe13

The open-access MAF lists 80 somatic variants for this specimen: 67 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, RNA 2, Intron 1, 3'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 436/577 reads (76%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALPK2 | c.3428C>G p.S1143C | Missense Mutation (SNP) | VAF 469/1352 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64491374, COSV64492932; called by muse, mutect2, varscan2
- ANKRD44 | c.1304A>T p.D435V | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56551283, COSV99985007; called by muse, mutect2, varscan2
- ASIC2 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 104/155 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV56757939, COSV99861304; called by muse, mutect2, varscan2
- C12orf50 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV53894135; called by muse, mutect2, varscan2
- CA6 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 169/210 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66261745; called by muse, mutect2, varscan2
- CACNA2D1 | c.2351G>A p.G784E (on ENST00000356253 / NM_001366867.1; = p.G772E on NM_000722.4) | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated (0.95); PolyPhen benign (0.115); catalogued as COSV62373270; called by muse, mutect2, varscan2
- CAPN1 | c.336G>A p.L112= | Splice Region (SNP) | VAF 224/513 reads (44%) | catalogued as COSV54197439; called by muse, mutect2, varscan2
- CD163 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 586/627 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63130654; called by muse, mutect2, varscan2
- CDHR2 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 64/70 reads (91%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as rs1395522059, COSV56136148; called by muse, mutect2, varscan2
- COL16A1 | c.603G>T p.R201S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1452530018, COSV54702485; called by muse, mutect2, varscan2
- CRB1 | c.1784C>G p.A595G | Missense Mutation (SNP) | VAF 210/412 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV66329112; called by muse, mutect2, varscan2
- DNAH10 | c.9907G>A p.E3303K (on ENST00000409039; = p.E3242K on NM_207437.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.033); catalogued as COSV68990234; called by muse, mutect2
- DSC1 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs757507124, COSV57143205; called by muse, mutect2, varscan2
- EGR1 | c.1000dup p.H334Pfs*13 | Frame Shift Ins (INS) | VAF 16/128 reads (13%) | catalogued as rs746692720; called by mutect2, varscan2
- ESX1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.53); catalogued as rs1187244448, COSV65424083; called by muse, varscan2
- FOXJ3 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs778053981, COSV62360597; called by muse, mutect2
- FRG2 | c.154A>T p.S52C | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV66459799; called by muse, mutect2, varscan2
- FRMD4A | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52714336; called by muse, mutect2, varscan2
- FRMD5 | c.1527G>A p.M509I | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68720897; called by muse, mutect2, varscan2
- FRY | c.7465G>T p.D2489Y | Missense Mutation (SNP) | VAF 210/361 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66567170; called by muse, mutect2, varscan2
- GALNT13 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67213840; called by muse, mutect2, varscan2
- GALNT6 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV62541852; called by muse, mutect2, varscan2
- GDPD2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65532410; called by muse, mutect2, varscan2
- GPI | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV62893541; called by muse, mutect2, varscan2
- GPR21 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 196/377 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.911); catalogued as rs1415151972, COSV65378874; called by muse, mutect2, varscan2
- GRIK2 | c.2627A>C p.K876T | Missense Mutation (SNP) | VAF 122/276 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV59720762; called by muse, mutect2, varscan2
- IGSF21 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV52127804; called by muse, mutect2, varscan2
- IL1A | c.789C>G p.D263E | Missense Mutation (SNP) | VAF 132/485 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV99641481; called by muse, mutect2, varscan2
- KCTD7 | c.776G>C p.*259Sext*19 (on ENST00000275532; = p.V272= on NM_153033.5) | Nonstop Mutation (SNP) | VAF 165/413 reads (40%) | catalogued as COSV51876543; called by muse, mutect2, varscan2
- KLHL14 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 159/371 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs773956260, COSV63830709; called by muse, mutect2, varscan2
- KRT72 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 157/347 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53373598; called by muse, mutect2, varscan2
- MAGI3 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 397/1111 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV56830898; called by muse, mutect2, varscan2
- MDC1 | c.4964C>G p.P1655R | Missense Mutation (SNP) | VAF 231/538 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64523855; called by muse, mutect2, varscan2
- NAT16 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55864385; called by muse, mutect2, varscan2
- NOLC1 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 103/121 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs758979469, COSV64180161; called by muse, mutect2, varscan2
- OSR1 | c.782C>A p.T261N | Missense Mutation (SNP) | VAF 130/166 reads (78%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.081); catalogued as COSV55344872; called by muse, mutect2, varscan2
- PCDHB13 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 121/152 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs782053306, COSV53394300; called by muse, mutect2, varscan2
- PDZRN3 | c.1624G>C p.V542L | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as rs563627189, COSV55194130; called by muse, mutect2, varscan2
- PLXNA4 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV58113377, COSV58165790; called by muse, mutect2, varscan2
- PROX1 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 224/451 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV54777117; called by muse, mutect2, varscan2
- PXN | c.1607C>A p.S536Y (on ENST00000228307 / NM_001080855.3; = p.S502Y on NM_002859.4) | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV57217796; called by muse, mutect2, varscan2
- RRN3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV52213781; called by muse, mutect2, varscan2
- SCEL | c.1081C>T p.H361Y (on ENST00000349847 / NM_144777.3; = p.H341Y on NM_003843.4) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV62993138; called by muse, mutect2, varscan2
- SI | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs754112650, COSV100013532, COSV104387854; called by muse, mutect2, varscan2
- SLC16A2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 204/557 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1263372106, COSV52083395; called by muse, mutect2, varscan2
- SLC26A3 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV60639338; called by muse, mutect2, varscan2
- SLC26A8 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV62885120, COSV62886216; called by muse, mutect2, varscan2
- SOX6 | c.2275A>G p.T759A (on ENST00000528429 / NM_001145819.2; = p.T732A on NM_017508.3) | Missense Mutation (SNP) | VAF 312/550 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57040755; called by muse, mutect2, varscan2
- TDRKH | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 219/431 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1474841348, COSV64316098; called by muse, mutect2, varscan2
- TENM4 | c.5504A>T p.N1835I | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53616632; called by muse, mutect2, varscan2
- TIMM44 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs201091980, COSV54490645; called by muse, mutect2, varscan2
- TNFAIP3 | c.2327A>G p.N776S | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52797482; called by muse, mutect2, varscan2
- TNN | c.3136G>A p.G1046S | Missense Mutation (SNP) | VAF 182/508 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53423414; called by muse, varscan2
- TRAT1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 360/910 reads (40%) | catalogued as rs148894492; called by muse, mutect2, varscan2
- ZNF266 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 153/325 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV63221692; called by muse, mutect2, varscan2
- ZNF615 | c.1933T>A p.F645I | Missense Mutation (SNP) | VAF 295/352 reads (84%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV65032413; called by muse, mutect2, varscan2
- ZNF804A | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753289146, COSV56440667; called by muse, mutect2, varscan2
- C5orf38 | c.279_293del p.H93_G97del | In Frame Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, varscan2
- CHDH | c.1540_1541del p.C514Hfs*3 | Frame Shift Del (DEL) | VAF 83/228 reads (36%) | called by mutect2, varscan2
- COL22A1 | c.2318G>T p.R773I | Missense Mutation (SNP) | VAF 58/2229 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2
- EIF3M | c.315-14_317del p.X105_splice | Splice Site (DEL) | VAF 21/116 reads (18%) | called by mutect2, pindel, varscan2
- FAT1 | c.9753A>C p.Q3251H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GPR149 | c.1475T>G p.F492C | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- L3MBTL3 | c.2242_2271del p.I748_G757del | In Frame Del (DEL) | VAF 54/136 reads (40%) | called by mutect2, pindel
- RFWD3 | c.1528_1544del p.R510Cfs*8 | Frame Shift Del (DEL) | VAF 44/65 reads (68%) | called by mutect2, pindel, varscan2
- RPP25L | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GPRC5B | c.498G>T p.A166= | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as rs1288522295; called by muse, mutect2
- GUCY1A2 | c.1716C>T p.Y572= | Silent (SNP) | VAF 118/151 reads (78%) | catalogued as COSV56481521, COSV56494249; called by muse, mutect2, varscan2
- HTR7 | c.618C>T p.V206= | Silent (SNP) | VAF 126/158 reads (80%) | catalogued as COSV53284426, COSV53290345; called by muse, mutect2, varscan2
- MAP2 | c.3681T>A p.S1227= | Silent (SNP) | VAF 193/412 reads (47%) | catalogued as COSV52285122; called by muse, mutect2, varscan2
- MAS1L | c.391T>C p.L131= | Silent (SNP) | VAF 86/205 reads (42%) | catalogued as rs779935263, COSV65808662; called by muse, mutect2, varscan2
- PDZRN4 | c.1245C>A p.G415= (on ENST00000402685 / NM_001164595.2; = p.G157= on NM_013377.4) | Silent (SNP) | VAF 78/271 reads (29%) | catalogued as COSV54196107; called by muse, mutect2, varscan2
- TFAP2D | c.1095T>C p.T365= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as COSV50410789; called by muse, mutect2, varscan2
- TGM6 | c.1587C>G p.V529= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV52478217; called by muse, varscan2
- TRIP11 | c.5604A>T p.L1868= | Silent (SNP) | VAF 597/684 reads (87%) | catalogued as COSV50915150; called by muse, mutect2, varscan2
- CPLANE1 | c.*2721A>T | 3'UTR (SNP) | VAF 116/344 reads (34%) | catalogued as COSV57055752; called by muse, mutect2, varscan2
- IGHV1-12 | n.23T>C | RNA (SNP) | VAF 64/143 reads (45%) | called by muse, mutect2, varscan2
- RPL23AP82 | n.683G>A | RNA (SNP) | VAF 43/65 reads (66%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2052G>A | Intron (SNP) | VAF 46/894 reads (5%) | called by muse, mutect2
